Somatic mutation profile of tumor specimen TCGA-F9-A7Q0-01A (aliquot TCGA-F9-A7Q0-01A-11D-A35Z-10) from TCGA case TCGA-F9-A7Q0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 37.0 years (13,523 days).
Specimen TCGA-F9-A7Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed825ce-8b2c-43da-9049-72dd7bb730f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F9-A7Q0-10B (Blood Derived Normal), aliquot TCGA-F9-A7Q0-10B-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edcf9d16-4581-4807-a4cc-23496879c8a7

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 3, Intron 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB2 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1438170860, COSV99401174; called by muse, mutect2, varscan2
- CLDN11 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs549752354, COSV50355194; called by muse, mutect2, varscan2
- DNM2 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs777564981, COSV100116772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4B | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 102/509 reads (20%) | catalogued as COSV101469193, COSV70529961; called by muse, mutect2, varscan2
- QARS1 | c.1304A>G p.Y435C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143462532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFFL | c.183G>A p.Q61= | Splice Region (SNP) | VAF 47/115 reads (41%) | catalogued as COSV99265172; called by muse, mutect2, varscan2
- RUVBL2 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs774049361, COSV99668828; called by muse, mutect2, varscan2
- SAV1 | c.1062T>A p.Y354* | Nonsense Mutation (SNP) | VAF 53/73 reads (73%) | catalogued as COSV100220646; called by muse, mutect2, varscan2
- STAT5B | c.2098G>C p.V700L | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV53180601, COSV99510666; called by muse, mutect2
- VIPR1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as rs771232178, COSV100285517; called by muse, mutect2, varscan2
- WNT2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750454001, COSV99625740; called by muse, mutect2, varscan2
- ZNF19 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV99867095; called by muse, mutect2, varscan2
- MUC16 | c.39345C>T p.P13115= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs1162346306, COSV101109620; called by muse, mutect2
- TTN | c.10360+4955A>G | Intron (SNP) | VAF 38/93 reads (41%) | catalogued as COSV100595669; called by muse, mutect2, varscan2
